Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HI, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HI-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

RIGHT UPPER ARM SOFT TISSUE, RESECTION:

Dedifferentiated liposarcoma (see comment).

Tumor size: 8 x 5.5 x 5 cm.

Tumor necrosis less than 10%.

Tumor involves the anterior, deep, proximal and distal margins.

Medial margin is negative.

Lateral margin is less than 1 mm.

COMMENT: The tumor is composed of well differentiated liposarcoma and dedifferentiated component that is a high grade sarcoma with spindle and pleomorphic cells, brisk mitosis (22 mitosis per high-power field), rich vasculature and myxoid stroma. The tumor dissects the skeletal muscle and present at multiple margins.

This case was reviewed prospectively at the

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by _____

Specimen(s) Received

A SOFT TISSUE SARCOMA RIGHT UPPER ARM

Clinical History

RIGHT ARM SOFT TISSUE SARCOMA

Preoperative Diagnosis

Right arm soft tissue sarcoma.

Frozen Section Diagnosis

No frozen section per

Gross Description

A. The specimen is received fresh in a container labeled "soft tissue sarcoma, right upper arm". The specimen consists of a 10.5 x 9.5 x 8 cm, well-encapsulated mass surrounded by a small amount of adipose tissue and muscle. Prior to sectioning, the specimen is inked as follows:

Proximal margin:	Blue
Distal:	Green
Anterior:	Orange
Deep:	Black
Medial:	Red
Lateral:	Yellow

ICD-O 3
Liposarcoma, dedifferentiated
8858/3
Site: @ Cum NOS C49.1
J 4/22/14

[page 2 of 2]
Sectioning into the tumor reveals an 8 x 5.5 x 5 cm, pale tan, soft mass which comes to 0.1 cm from the anterior margin, 0.6 cm from the deep margin, 0.8 cm from the proximal margin, 1.5 cm from the distal margin, 2.2 cm from the medial margin and 0.1 cm from the lateral margin. Representative sections are submitted as follows:

- A1-A2: Perpendicular sections of the tumor in relation to the anterior margin
- A3-A4: Perpendicular sections of the tumor in relation to the deep margin
- A5-A6: Perpendicular sections of the tumor in relation to the proximal margin
- A7-A8: Perpendicular sections of the distal margin
- A9-A10: Perpendicular sections of the medial margin
- A11-A12: Perpendicular sections of the lateral margin
- A13: Additional sections of the tumor

Representative section was submitted for the

Source: NCI Genomic Data Commons file b0fb7b85-8b68-4553-b077-3687bb402d7b (TCGA-3B-A9HI.075D4107-9DD0-49E4-9E1E-B25A1B5128FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).